Somatic mutation profile of cancer-model specimen HCM-CSHL-0085-C24-85M (3D Organoid; aliquot HCM-CSHL-0085-C24-85M-01D-A78L-36), derived from the metastatic tumor of HCMI case HCM-CSHL-0085-C24, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Ampulla of Vater; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 56.0 years (20,466 days).
Specimen HCM-CSHL-0085-C24-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 06fa2e97-9679-4b6b-b992-af0b19621f7c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0085-C24-10A (Blood Derived Normal), aliquot HCM-CSHL-0085-C24-10A-01D-A78L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8a475518-c500-4298-8401-d99dffb60a1c

The open-access MAF lists 131 somatic variants for this specimen: 91 protein-altering or splice-affecting, 31 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 79, Silent 31, Intron 3, Splice Region 3, RNA 3, Nonsense Mutation 2, Translation Start Site 2, 5'Flank 2, Splice Site 2, 5'UTR 1, Frame Shift Ins 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.121A>G p.T41A | Missense Mutation (SNP) | VAF 171/347 reads (49%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as rs121913412, COSV62687862, COSV62689580, COSV62714770; ClinVar: conflicting interpretations of pathogenicity / pathogenic /  other / likely pathogenic; called by muse, mutect2, varscan2
- AC013489.1 | c.568G>A p.D190N | Missense Mutation (SNP) | VAF 87/130 reads (67%) | SIFT tolerated (0.19); PolyPhen benign (0.259); catalogued as COSV51552966; called by muse, mutect2, varscan2
- ADGRB1 | c.2202G>A p.A734= | Splice Region (SNP) | VAF 44/88 reads (50%) | catalogued as rs753558928; called by muse, mutect2, varscan2
- ADGRB1 | c.4604G>A p.R1535Q | Missense Mutation (SNP) | VAF 158/310 reads (51%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.988); catalogued as COSV60097426; called by muse, mutect2, varscan2
- AIM2 | c.442G>T p.G148W | Missense Mutation (SNP) | VAF 34/148 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.463); catalogued as COSV100931079; called by muse, mutect2
- ANK2 | c.2365G>A p.A789T | Missense Mutation (SNP) | VAF 275/602 reads (46%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.596); catalogued as rs1238418730; called by muse, mutect2, varscan2
- ARID2 | c.1352del p.S451Lfs*12 | Frame Shift Del (DEL) | VAF 121/165 reads (73%) | catalogued as COSV57600163; called by mutect2, pindel, varscan2
- CALHM2 | c.824G>A p.R275Q | Missense Mutation (SNP) | VAF 88/223 reads (39%) | SIFT tolerated (0.25); PolyPhen benign (0.322); catalogued as rs377104588; called by muse, mutect2, varscan2
- CLTCL1 | c.541A>G p.M181V | Missense Mutation (SNP) | VAF 84/280 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.666); catalogued as rs1555966213; called by muse, mutect2, varscan2
- CSN1S1 | c.370C>T p.R124C | Missense Mutation (SNP) | VAF 40/101 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.311); catalogued as rs372612450, COSV55891851; called by muse, mutect2, varscan2
- DACT3 | c.617C>T p.A206V | Missense Mutation (SNP) | VAF 58/196 reads (30%) | SIFT tolerated (0.62); PolyPhen possibly damaging (0.564); catalogued as rs1267678211; called by muse, mutect2, varscan2
- EPHA1 | c.2671C>T p.R891W | Missense Mutation (SNP) | VAF 59/124 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs767930814; called by muse, mutect2, varscan2
- ESPNL | c.2083C>T p.R695C | Missense Mutation (SNP) | VAF 88/231 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs927691376; called by muse, mutect2, varscan2
- FANCM | c.325G>C p.V109L | Missense Mutation (SNP) | VAF 20/652 reads (3%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV53532773; called by muse, mutect2
- FCGRT | c.877C>G p.P293A | Missense Mutation (SNP) | VAF 126/537 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.137); catalogued as COSV54543655; called by muse, mutect2, varscan2
- FERD3L | c.97T>G p.F33V | Missense Mutation (SNP) | VAF 57/126 reads (45%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as COSV51761712; called by muse, mutect2, varscan2
- FSTL5 | c.1507_1508dup p.W503Cfs*37 | Frame Shift Ins (INS) | VAF 76/181 reads (42%) | catalogued as COSV60196626; called by mutect2, varscan2
- HCAR2 | c.985G>A p.V329I | Missense Mutation (SNP) | VAF 38/682 reads (6%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs200174813, COSV61024981; called by muse, mutect2
- HCAR3 | c.985G>A p.V329I | Missense Mutation (SNP) | VAF 121/415 reads (29%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs368546949; called by muse, mutect2, varscan2
- HOGA1 | c.284G>A p.R95H | Missense Mutation (SNP) | VAF 163/342 reads (48%) | SIFT tolerated (0.56); PolyPhen benign (0.023); catalogued as rs754634699, COSV65706481; called by muse, mutect2, varscan2
- ICAM5 | c.588C>A p.F196L | Missense Mutation (SNP) | VAF 172/362 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV55748939; called by muse, mutect2, varscan2
- ITCH | c.1970C>T p.T657M (on ENST00000262650 / NM_001257137.3; = p.T616M on NM_031483.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 124/657 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1445655265, COSV52933847; called by muse, mutect2, varscan2
- KLHL1 | c.1769G>A p.R590Q | Missense Mutation (SNP) | VAF 54/102 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748882149, COSV64769060, COSV64786398; called by muse, mutect2, varscan2
- LRRTM4 | c.961C>T p.P321S | Missense Mutation (SNP) | VAF 120/120 reads (100%) | SIFT tolerated (0.41); PolyPhen benign (0.259); catalogued as COSV69142997; called by muse, mutect2, varscan2
- MAGEE1 | c.2398A>G p.T800A | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.929); catalogued as rs781960739; called by muse, mutect2, varscan2
- MCRIP1 | c.28G>A p.V10M | Missense Mutation (SNP) | VAF 54/104 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs754717613; called by muse, mutect2, varscan2
- NBEA | c.2118A>G p.I706M | Missense Mutation (SNP) | VAF 53/143 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1365413222; called by muse, mutect2, varscan2
- OR2J2 | c.125G>A p.G42E | Missense Mutation (SNP) | VAF 69/157 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs755187820; called by muse, mutect2, varscan2
- OR4A16 | c.260A>C p.K87T | Missense Mutation (SNP) | VAF 220/221 reads (100%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.066); catalogued as COSV59042819; called by muse, mutect2, varscan2
- P2RY14 | c.937C>A p.P313T | Missense Mutation (SNP) | VAF 67/136 reads (49%) | SIFT tolerated (0.48); PolyPhen benign (0.005); catalogued as COSV56391075; called by muse, mutect2, varscan2
- PABPC3 | c.1109G>A p.R370H | Missense Mutation (SNP) | VAF 156/370 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs773025278, COSV99879495; called by muse, varscan2
- PARP10 | c.2545C>T p.R849C | Missense Mutation (SNP) | VAF 78/164 reads (48%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as rs782649313, COSV57299228; called by muse, mutect2, varscan2
- PCDHB15 | c.1246G>A p.E416K | Missense Mutation (SNP) | VAF 102/227 reads (45%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.612); catalogued as rs1554292027; called by muse, mutect2, varscan2
- PLEKHM3 | c.1309C>T p.R437* | Nonsense Mutation (SNP) | VAF 172/172 reads (100%) | catalogued as rs1447181721; called by muse, mutect2, varscan2
- PLXND1 | c.2627G>A p.R876H | Missense Mutation (SNP) | VAF 89/217 reads (41%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.92); catalogued as rs554042254; called by muse, mutect2, varscan2
- PRR23A | c.779G>A p.R260H | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.04); catalogued as COSV67214028; called by muse, mutect2, varscan2
- RAD50 | c.1892A>C p.D631A | Missense Mutation (SNP) | VAF 165/370 reads (45%) | SIFT tolerated (0.19); PolyPhen benign (0.013); catalogued as rs1372866109; called by muse, mutect2, varscan2
- RTN4RL1 | c.1310C>T p.A437V | Missense Mutation (SNP) | VAF 38/450 reads (8%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as rs774569320; called by muse, mutect2
- RYR3 | c.13120C>T p.R4374W (on ENST00000389232; = p.R4375W on NM_001036.6) | Missense Mutation (SNP) | VAF 119/421 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs759909362, COSV66778249; called by muse, mutect2, varscan2
- SIRPB1 | c.432C>T p.R144= | Splice Region (SNP) | VAF 143/554 reads (26%) | catalogued as rs200840558, COSV53537445; called by muse, mutect2, varscan2
- SRD5A1 | c.556C>T p.P186S | Missense Mutation (SNP) | VAF 164/164 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57014835; called by muse, mutect2, varscan2
- TDRD9 | c.4082G>A p.R1361H | Missense Mutation (SNP) | VAF 93/192 reads (48%) | SIFT tolerated (0.42); PolyPhen benign (0.132); catalogued as rs142470189; called by muse, mutect2, varscan2
- TMEM63C | c.1132G>A p.V378I | Missense Mutation (SNP) | VAF 83/203 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.014); catalogued as rs374759104; called by muse, mutect2, varscan2
- TPTE2 | c.452C>G p.P151R | Missense Mutation (SNP) | VAF 60/130 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.143); catalogued as COSV55023847; called by muse, mutect2, varscan2
- TRDN | c.278G>A p.R93H | Missense Mutation (SNP) | VAF 43/91 reads (47%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1371219098, COSV100522147; called by muse, mutect2, varscan2
- TTN | c.31129G>A p.A10377T (on ENST00000591111; = p.A9450T on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 90/91 reads (99%) | PolyPhen benign (0.025); catalogued as rs756672871; called by muse, mutect2, varscan2
- UNC5C | c.2225G>A p.R742H | Missense Mutation (SNP) | VAF 69/164 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs142722408; called by muse, mutect2, varscan2
- ZSCAN9 | c.987G>C p.Q329H | Missense Mutation (SNP) | VAF 104/236 reads (44%) | SIFT tolerated (0.13); PolyPhen benign (0.378); catalogued as COSV99356463; called by muse, mutect2, varscan2
- ABCA4 | c.4988T>C p.L1663P | Missense Mutation (SNP) | VAF 26/260 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.565); called by muse, mutect2, varscan2
- ACO1 | c.241G>A p.A81T | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.648); called by muse, mutect2
- ANK2 | c.2694-4C>T | Splice Region (SNP) | VAF 182/407 reads (45%) | called by muse, mutect2, varscan2
- ANXA1 | c.154C>T p.H52Y | Missense Mutation (SNP) | VAF 34/232 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.53); called by muse, mutect2, varscan2
- AP5M1 | c.593G>A p.W198* | Nonsense Mutation (SNP) | VAF 289/289 reads (100%) | called by muse, mutect2, varscan2
- ASCL3 | c.17G>T p.G6V | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.037); called by mutect2, varscan2
- CCDC141 | c.1684C>A p.Q562K | Missense Mutation (SNP) | VAF 79/79 reads (100%) | SIFT tolerated (0.32); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CDH12 | c.1967A>C p.N656T | Missense Mutation (SNP) | VAF 128/246 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- CENPF | c.4147C>A p.P1383T | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.018); called by mutect2, varscan2
- CIB1 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- CUL4A | c.1858+1G>T p.X620_splice (on ENST00000375440 / NM_001008895.4; = p.X520_splice on NM_003589.3) | Splice Site (SNP) | VAF 94/244 reads (39%) | called by muse, mutect2, varscan2
- CYP7B1 | c.16T>C p.S6P | Missense Mutation (SNP) | VAF 12/262 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2
- DCLK1 | c.1944+2T>G p.X648_splice | Splice Site (SNP) | VAF 45/102 reads (44%) | called by muse, mutect2, varscan2
- DCLK1 | c.1418T>A p.L473H | Missense Mutation (SNP) | VAF 87/175 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DHX33 | c.1327A>G p.M443V | Missense Mutation (SNP) | VAF 99/206 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ESF1 | c.1712G>C p.S571T | Missense Mutation (SNP) | VAF 115/170 reads (68%) | SIFT tolerated (0.18); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- GPR75 | c.740C>A p.S247Y | Missense Mutation (SNP) | VAF 245/245 reads (100%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- HMCN2 | c.12859G>C p.E4287Q | Missense Mutation (SNP) | VAF 118/266 reads (44%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.832); called by muse, mutect2, varscan2
- HNRNPLL | c.1196G>T p.G399V | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IPO7 | c.868G>A p.E290K | Missense Mutation (SNP) | VAF 102/102 reads (100%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.745); called by muse, mutect2, varscan2
- KNDC1 | c.3543G>C p.R1181S | Missense Mutation (SNP) | VAF 103/449 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- LRRC66 | c.624C>G p.F208L | Missense Mutation (SNP) | VAF 68/88 reads (77%) | SIFT tolerated (0.11); PolyPhen benign (0.177); called by muse, mutect2, varscan2
- NRDC | c.2434G>C p.D812H | Missense Mutation (SNP) | VAF 97/97 reads (100%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- PHKG1 | c.537G>C p.E179D | Missense Mutation (SNP) | VAF 52/107 reads (49%) | SIFT tolerated (0.14); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- PIP5K1C | c.1819G>A p.A607T | Missense Mutation (SNP) | VAF 295/616 reads (48%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- PLK2 | c.1051G>C p.V351L | Missense Mutation (SNP) | VAF 95/95 reads (100%) | SIFT tolerated (0.13); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- PPP1R3A | c.2363G>T p.C788F | Missense Mutation (SNP) | VAF 71/142 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PRKDC | c.1068_1070del p.N356del | In Frame Del (DEL) | VAF 42/144 reads (29%) | called by pindel, varscan2
- PTGER3 | c.463C>T p.R155W | Missense Mutation (SNP) | VAF 102/186 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RGS20 | c.559G>A p.A187T (on ENST00000297313 / NM_170587.4; = p.A40T on NM_003702.4) | Missense Mutation (SNP) | VAF 70/148 reads (47%) | SIFT tolerated (0.17); PolyPhen benign (0.041); called by muse, varscan2
- RNF6 | c.349T>C p.F117L | Missense Mutation (SNP) | VAF 100/267 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.723); called by muse, mutect2, varscan2
- RYR3 | c.6783A>C p.Q2261H | Missense Mutation (SNP) | VAF 33/92 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- SEMA3A | c.1003T>G p.F335V | Missense Mutation (SNP) | VAF 49/89 reads (55%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SF3A3 | c.46G>A p.E16K | Missense Mutation (SNP) | VAF 150/151 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- SLC6A4 | c.1387G>C p.E463Q | Missense Mutation (SNP) | VAF 117/117 reads (100%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TCF20 | c.2605G>T p.D869Y | Missense Mutation (SNP) | VAF 23/160 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TTN | c.56612A>C p.K18871T (on ENST00000591111; = p.K11447T on NM_003319.4) | Missense Mutation (SNP) | VAF 32/32 reads (100%) | PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- XYLT2 | c.456G>C p.Q152H | Missense Mutation (SNP) | VAF 318/318 reads (100%) | SIFT tolerated (0.06); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ZBTB16 | c.7C>G p.L3V | Missense Mutation (SNP) | VAF 102/284 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.025); called by muse, varscan2
- ZDHHC6 | c.404G>A p.C135Y | Missense Mutation (SNP) | VAF 148/237 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF365 | c.833T>G p.L278R | Missense Mutation (SNP) | VAF 83/479 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- ZNF385D | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 57/127 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ZSCAN29 | c.380C>T p.S127L | Missense Mutation (SNP) | VAF 65/87 reads (75%) | SIFT tolerated (0.21); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- AKIRIN1 | c.393A>G p.T131= | Silent (SNP) | VAF 64/125 reads (51%) | catalogued as rs1298893257; called by muse, mutect2, varscan2
- ALPK2 | c.3045C>T p.T1015= | Silent (SNP) | VAF 72/72 reads (100%) | catalogued as rs541753586; called by muse, mutect2, varscan2
- ANKRD1 | c.657C>A p.L219= | Silent (SNP) | VAF 248/569 reads (44%) | catalogued as COSV100865362; called by muse, mutect2, varscan2
- ARPP21 | c.1317A>G p.A439= | Silent (SNP) | VAF 141/333 reads (42%) | catalogued as COSV51806064; called by muse, mutect2, varscan2
- ASCL3 | c.18C>T p.G6= | Silent (SNP) | VAF 23/52 reads (44%) | catalogued as COSV100366920; called by muse, mutect2, varscan2
- BAHCC1 | c.5625G>A p.S1875= | Silent (SNP) | VAF 31/69 reads (45%) | catalogued as rs371234536; called by muse, mutect2, varscan2
- C3AR1 | c.183C>T p.F61= | Silent (SNP) | VAF 118/223 reads (53%) | called by muse, mutect2, varscan2
- CCDC160 | c.582G>A p.T194= | Silent (SNP) | VAF 157/157 reads (100%) | catalogued as rs751796060, COSV66251327; called by muse, mutect2, varscan2
- CLCA1 | c.1791G>A p.T597= | Silent (SNP) | VAF 207/461 reads (45%) | catalogued as rs899149911, COSV52327435; called by muse, mutect2, varscan2
- DDX3X | c.228T>C p.D76= (on ENST00000399959; = p.D77= on NM_001356.5) | Silent (SNP) | VAF 79/79 reads (100%) | called by muse, mutect2, varscan2
- DEPDC5 | c.2256G>T p.L752= (on ENST00000400246; = p.L821= on NM_014662.5) | Silent (SNP) | VAF 96/142 reads (68%) | called by muse, mutect2, varscan2
- ELFN1 | c.1845G>A p.G615= | Silent (SNP) | VAF 11/320 reads (3%) | catalogued as rs1196057245; called by muse, mutect2
- FAM209A | c.447G>A p.K149= | Silent (SNP) | VAF 129/190 reads (68%) | called by muse, mutect2, varscan2
- FAT4 | c.10095A>C p.R3365= | Silent (SNP) | VAF 124/234 reads (53%) | called by muse, mutect2, varscan2
- GRIN1 | c.114C>T p.H38= | Silent (SNP) | VAF 154/334 reads (46%) | catalogued as rs1241572680, COSV59300354; called by muse, mutect2, varscan2
- HDAC7 | c.1980T>C p.G660= (on ENST00000427332; = p.G699= on NM_015401.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 131/131 reads (100%) | called by muse, mutect2, varscan2
- IGLV3-1 | c.228C>T p.I76= | Silent (SNP) | VAF 267/939 reads (28%) | catalogued as rs368264920; called by muse, mutect2, varscan2
- IL4 | c.147C>T p.T49= | Silent (SNP) | VAF 47/126 reads (37%) | catalogued as rs759103191; called by muse, mutect2, varscan2
- KRT5 | c.75G>A p.P25= | Silent (SNP) | VAF 70/155 reads (45%) | catalogued as rs572849401; called by muse, mutect2, varscan2
- MDGA2 | c.372A>T p.G124= | Silent (SNP) | VAF 209/209 reads (100%) | called by muse, mutect2, varscan2
- OR56B4 | c.810G>A p.E270= | Silent (SNP) | VAF 387/388 reads (100%) | called by muse, mutect2, varscan2
- PAXIP1 | c.2868C>T p.F956= | Silent (SNP) | VAF 99/212 reads (47%) | called by muse, mutect2, varscan2
- PROM1 | c.2094C>T p.S698= | Silent (SNP) | VAF 25/86 reads (29%) | catalogued as rs199727800, CM1312881; called by muse, mutect2, varscan2
- RFPL4A | c.720A>G p.T240= | Silent (SNP) | VAF 293/2645 reads (11%) | catalogued as rs757162286; called by muse, mutect2, varscan2
- RFPL4AL1 | c.720A>G p.T240= | Silent (SNP) | VAF 27/67 reads (40%) | called by mutect2, varscan2
- SLC22A23 | c.1164G>A p.Q388= | Silent (SNP) | VAF 24/52 reads (46%) | catalogued as rs768889057; called by muse, mutect2, varscan2
- SYDE1 | c.819C>T p.Y273= | Silent (SNP) | VAF 53/94 reads (56%) | catalogued as rs1413962871; called by muse, mutect2, varscan2
- TFEB | c.37C>A p.R13= | Silent (SNP) | VAF 72/161 reads (45%) | catalogued as COSV57824244; called by muse, mutect2, varscan2
- TRPM8 | c.2286G>A p.S762= | Silent (SNP) | VAF 515/515 reads (100%) | catalogued as rs199933698, COSV61222637; called by muse, mutect2, varscan2
- UBE3A | c.1372C>T p.L458= | Silent (SNP) | VAF 88/275 reads (32%) | called by muse, mutect2, varscan2
- ZWILCH | c.1020C>T p.F340= | Silent (SNP) | VAF 97/254 reads (38%) | catalogued as rs769354705; called by muse, mutect2, varscan2
- CREB5 | chr7:28409791 G>A | 5'Flank (SNP) | VAF 36/76 reads (47%) | catalogued as rs1461952039; called by muse, mutect2, varscan2
- FOXP2 | c.168+36459C>T | Intron (SNP) | VAF 43/70 reads (61%) | called by muse, mutect2, varscan2
- HAS1 | c.10-25C>T | Intron (SNP) | VAF 52/248 reads (21%) | catalogued as rs1225187612; called by muse, mutect2
- LEPR | c.-120C>G | 5'UTR (SNP) | VAF 286/286 reads (100%) | called by muse, mutect2, varscan2
- OR4N3P | n.687T>G | RNA (SNP) | VAF 16/43 reads (37%) | called by mutect2, varscan2
- OSBPL2 | chr20:62233193 C>T | 5'Flank (SNP) | VAF 82/316 reads (26%) | catalogued as rs375508203; called by muse, mutect2, varscan2
- PARGP1 | n.1966C>T | RNA (SNP) | VAF 91/359 reads (25%) | catalogued as rs1374034744; called by muse, mutect2, varscan2
- UBTFL2 | n.483A>G | RNA (SNP) | VAF 522/530 reads (98%) | catalogued as rs1433232626; called by muse, mutect2, varscan2
- ZNF589 | c.97-3971G>A | Intron (SNP) | VAF 105/219 reads (48%) | called by muse, mutect2, varscan2
